Somatic mutation profile of tumor specimen TCGA-QQ-A5VB-01A (aliquot TCGA-QQ-A5VB-01A-11D-A36J-09) from TCGA case TCGA-QQ-A5VB, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 53.8 years (19,654 days).
Specimen TCGA-QQ-A5VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5f69407-cef6-48af-880b-9abfaf165768.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A5VB-11B (Solid Tissue Normal), aliquot TCGA-QQ-A5VB-11B-11D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee8d806d-92cd-4c46-a664-f6e2027e7fce

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Frame Shift Del 5, Splice Site 1, Frame Shift Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD15 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs528380562, COSV100213022; called by muse, mutect2, varscan2
- ANK1 | c.5521G>A p.D1841N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs143987736; called by muse, mutect2, varscan2
- ARFGEF3 | c.4985G>A p.R1662Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.289); catalogued as rs757461478, COSV99294236; called by muse, mutect2, varscan2
- ATP2B1 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99665954; called by muse, mutect2, varscan2
- B3GNT2 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as rs1379408690, COSV57344875; called by muse, mutect2, varscan2
- BNC1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs968421847, COSV61756810; called by muse, mutect2, varscan2
- CHPF | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as rs753681580, COSV99704548; called by muse, mutect2, varscan2
- CLNK | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776088269, COSV99904351; called by muse, mutect2, varscan2
- CRNKL1 | c.1337A>G p.Q446R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as rs1392375190, COSV101057077; called by muse, mutect2, varscan2
- DBN1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99446353; called by muse, mutect2, varscan2
- HMBOX1 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99816391; called by muse, mutect2, varscan2
- LRG1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100015000; called by muse, mutect2, varscan2
- LRP1B | c.3527G>A p.C1176Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67249008; called by mutect2, varscan2
- MKRN3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1355723562, COSV58812455; called by muse, mutect2, varscan2
- MYOM3 | c.2859-1G>C p.X953_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100293350; called by muse, mutect2, varscan2
- NRXN2 | c.2825T>C p.L942P | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99635152; called by muse, mutect2
- PDE1C | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV100373228, COSV58517843; called by muse, mutect2, varscan2
- PHF21B | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100503979; called by muse, mutect2, varscan2
- PLXNA2 | c.171_172insT p.G58Wfs*15 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | catalogued as COSV100885670; called by mutect2, pindel, varscan2
- PRAMEF17 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.793); catalogued as COSV65816366; called by muse, mutect2
- PTPRU | c.1289G>C p.S430T | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100113361; called by muse, mutect2, varscan2
- RASA3 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763872615, COSV100480974; called by muse, mutect2, varscan2
- RPS26 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV100009240; called by muse, mutect2, varscan2
- SLC22A7 | c.1073A>T p.N358I (on ENST00000372585 / NM_153320.2; = p.N356I on NM_006672.3) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV99240490; called by muse, mutect2, varscan2
- SMARCAL1 | c.2624A>G p.K875R | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100619989; called by muse, mutect2, varscan2
- SYNDIG1L | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs367970781; called by muse, mutect2, varscan2
- TMPRSS9 | c.3152A>C p.E1051A (on ENST00000648592; = p.E1017A on NM_182973.2) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV99296067; called by muse, mutect2, varscan2
- TNR | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV99691516; called by muse, mutect2
- TP53 | c.824del p.C275Lfs*70 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; called by mutect2, pindel, varscan2
- UNC79 | c.1552A>C p.T518P (on ENST00000393151 / NM_001346218.2; = p.T341P on NM_020818.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99829071; called by muse, mutect2, varscan2
- WNT5A | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV99224956; called by muse, mutect2, varscan2
- FBXO5 | c.943del p.T315Pfs*55 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- KMT2C | c.14075del p.G4692Afs*24 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- PCDHA2 | c.734_737del p.S245Ffs*4 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- PRKDC | c.10799del p.P3600Lfs*2 | Frame Shift Del (DEL) | VAF 54/99 reads (55%) | called by mutect2, pindel, varscan2
- RIOX1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- C19orf53 | c.138G>A p.Q46= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as rs202134028, COSV99237659; called by muse, mutect2, varscan2
- DOCK4 | c.5742C>T p.V1914= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV101447920; called by muse, mutect2, varscan2
- IGLV3-16 | c.240C>T p.F80= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- KIF19 | c.387C>T p.N129= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs747262363, COSV100738912; called by muse, mutect2, varscan2
- PAQR5 | c.462C>A p.A154= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100575570; called by muse, mutect2, varscan2
- PSPC1 | c.828A>G p.A276= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1469802712, COSV58888646; called by muse, mutect2, varscan2
- ROBO2 | c.3669C>T p.D1223= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs2272164, COSV59901154; called by muse, mutect2, varscan2
- TC2N | c.1173G>T p.V391= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100563000; called by muse, mutect2, varscan2
- WDFY3 | c.2196C>T p.S732= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs761030925, COSV55703648; called by muse, mutect2, varscan2
- DOK3 | c.-69G>A | 5'UTR (SNP) | VAF 35/56 reads (63%) | catalogued as rs372299396; called by muse, mutect2, varscan2
- FAM183BP | n.1334C>A | RNA (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
